Gene-level copy-number profile of tumor specimen TCGA-36-2547-01A from TCGA case TCGA-36-2547, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 64.9 years (23,706 days).
Specimen TCGA-36-2547-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.7de81bd9-018a-46cc-9ca5-e1726b2ce951.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-36-2547-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c79c32ab-38a7-4fb6-a487-caef342b3fa2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,987; copy number 2: 17,323; copy number 3: 18,069; copy number 4: 11,808; copy number 5: 6,688; copy number 6: 2,887; copy number 7: 773; copy number 8: 105; copy number 9: 128; copy number 11: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-36-2547-01A-01D-1043-01): tumor purity 0.8, ploidy 3.15, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,045 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:175,307,218–181,808,084, 104 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr2:43,620,878–47,176,511, 74 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr6:167,607–2,245,605, 34 genes, copy number 9: AL035696.2, AL035696.3, AL035696.4, AL035696.1, AL365272.1, DUSP22, IRF4, AL512308.1, EXOC2, AL031770.1, HUS1B, AL357054.1, AL357054.2, AL357054.4, AL357054.5, AL357054.3, AL392183.1, AL356130.1, LINC01622, AL033381.2, AL033381.1, AL033381.3, FOXQ1, LINC01394, AL034346.1, FOXF2, MIR6720, RN7SL352P, AL512329.1, AL512329.2, FOXCUT, FOXC1, GMDS, AL035693.1.
- chr6:2,341,450–2,386,110, 2 genes, copy number 9 (within-gene range 6–9): HMGN2P28, AL031768.2.
- chr6:4,304,942–21,232,404, 259 genes, copy number 7–11 (within-gene range 6–11) (broad region; genes not listed).
- chr7:99,238,829–121,309,842, 422 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr9:69,324,567–75,724,575, 76 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr18:20,946,906–24,162,211, 72 genes, copy number 7 (broad region; genes not listed).
- chr18:24,170,505–24,179,295, 2 genes, copy number 7: RNA5SP452, Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 1,913. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
